Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A0XD, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A0XD-01A (Primary Tumor).

TSS Patient ID: Sample Procurement: Date:

Gender: Date of Birth:
Vital Status: Deceased Date of Death:

Race: White Ethnicity: Not Hispanic or Latino Specific Ethnicity:

Histologic Subtype: Colon adenocarcinoma Date of Initial Path Dx:
Primary Site: Colons Anatomic Site: Cecum
T Stage: 3 N Stage: 0 M Stage: 0 Overall Stage: IIA

Date of Normal Procurement:

ICD-0-3
adenocarcinoma, NOS 8140/3
Site: Cecum C18.0

JW
6/11/12

Source: NCI Genomic Data Commons file 7614ea99-e850-42c6-a835-7ce4b2f8c7d0 (TCGA-DM-A0XD.4D0D9EE2-7FEF-4E5F-922C-EE98200C4C61.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).